Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7593, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7593-01A (Primary Tumor).

Reg#: [REDACTED] Name: [REDACTED] DOB: [REDACTED] Sex: [REDACTED] Age: [REDACTED] User Name: [REDACTED]

ACCN Number	Order Test Code	Order Test Name	Last Updated
ACCN [REDACTED] Collected [REDACTED]	SPF	SP FINAL REPORT	Updated [REDACTED]
SP FINAL REPORT Source:			

HISTORY:

Ten-month history of right neck mass. Had a DL which showed asymmetrical enlargement of right tongue base and vallecula. Biopsies were positive for squamous cell carcinoma. Operative Procedure/Tissue Submitted: DLE and biopsy.

GROSS:

1. "Right base of tongue" Received in formalin in a small container is a 0.7 cm tan-pink mucosal bit. Bisected. (2ns)

MICROSCOPIC DIAGNOSIS:

1. Right base of tongue, biopsy: Invasive, non-keratinizing, poorly-differentiated squamous cell carcinoma.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

(electronic signature)

Close

Source: NCI Genomic Data Commons file ccfdf887-0cf5-49ba-b023-a8c68d59e0c3 (TCGA-DQ-7593.54FB44D2-E0EA-45AC-96A7-2208EC91EA72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).